Surgical pathology report (de-identified scan), TCGA case TCGA-DU-A7T6, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-A7T6-01A (Primary Tumor).

[page 1 of 2]
Anatomic Pathology/Cytology Document State: (version)

Update Date/Time:

Final 1

Patient Name:

MRN:

Service Date/Time:

DOB/Age/Gender:

Female Provider:

Location: Responsible Staff:

ICD 0.3
Oligodendroglioma, grade III
9451/3
Site Brain, supratentorial
C71.0
Brain NOS
C71.9
4/22/14

COPY TO:

PATHOLOGICAL DIAGNOSIS:

A. BRAIN, SITE NOT SPECIFIED, EXCISIONAL BIOPSY: GLIOMA, HIGH HISTOLOGICAL GRADE, CONSISTENT WITH OLIGODENDROGLIOMA.
B. BRAIN, RECURRENT TUMOR, EXCISION: ANAPLASTIC OLIGODENDROGLIOMA.
C. BRAIN, RECURRENT TUMOR, EXCISION: ANAPLASTIC OLIGODENDROGLIOMA.
MIB-1 PROLIFERATION INDEX: 50%.
SEE MICROSCOPIC AND COMMENT.

Operation/Specimen: Recurrent brain tumor; subfrontal dropped metastasis.

Clinical History and Pre-Op Dx: year old woman with past history of 2 surgeries for oligodendroglioma. Currently, large recurrence, multicystic.

GROSS PATHOLOGY:

A. Received fresh, one fragment, 0.5 cm across. Soft, tannish-gray. In total #1.

INTRAOPERATIVE CONSULTATION: Brain, smears: Glioma (C/W oligodendroglioma, high histological grade).

B.

SPECIMEN: 3, subfrontal dropped metastasis.

FIXATIVE: Saline.

GENERAL: A 1.1 x 0.7 x 0.3 cm. soft red-tan tissue fragment.

SECTIONS: 2, all submitted.

C.

SPECIMEN: 2, permanent recurrent brain tumor.

FIXATIVE: Saline.

GENERAL: A 2.5 x 2.4 x 1.0 cm., 2.5 gm. aggregate of soft, red to gray-tan brain tissue.

SECTIONS: 3-5 - all submitted.

MICROSCOPIC: A. Small fragments of brain infiltrated and focally effaced by a glial neoplastic proliferation. The neoplastic cells have round nuclei with occasional perinuclear halos. There is prominent karyorrhexis, mitotic figures are found without difficulty, and there is microvascular cellular proliferation.

B. Portions of a solid glial neoplasm. The neoplastic cells have large round nuclei with moderate pleomorphism. The background is finely fibrillary with microvesicular change. The vascularity is capillary-type with focal "chicken-wire" pattern. There is prominent endothelial and microvascular cellular proliferation, focally. There are mitotic figures throughout the neoplasm. There is no necrosis.

C. Portions of brain extensively effaced by a glial neoplastic

[page 2 of 2]
proliferation similar to that one described for parts A and B.
In here, the neoplasm seems to be growing in the leptomeningeal space.
The focally surrounding white matter is rarefied and gliotic.

IMMUNOHISTOCHEMISTRY: Immunoperoxidase methods for GFAP, MIB-1, and factor VIII antigen were performed on sections from block #4.

The GFAP demonstrates numerous gliofibrillary oligodendrocytes and minigemistocytes. With the MIB-1 a proliferation index of 50% is determined in the more active areas. The factor VIII depicts a high density of microvessels and prominent microvascular cellular proliferation.

COMMENT: The neoplasm present in the three specimens is an oligodendroglioma with prominent cellularity, mitotic activity, and microvascular cellular proliferation, features of an anaplastic oligodendroglioma. The MIB-1 proliferation index is 50%. The neoplasm seems to be growing in the leptomeninges.

TISSUE COMMITTEE CODE:

ICD9: 191.1

BILLING CODES:

Source: NCI Genomic Data Commons file 25316c7a-59c8-4294-8229-4699ffaea0ba (TCGA-DU-A7T6.B14319BC-DB5D-41E4-9954-5E6641791D54.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).